Surgical pathology report (de-identified scan), TCGA case TCGA-A4-8311, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-A4-8311-01A (Primary Tumor).

[page 1 of 2]
CONCURRENT PATHOLOGY REPORT

DIAGNOSIS

DIAGNOSIS:

A. Deep margin, left renal mass, biopsy with frozen section:
Benign renal parenchyma; negative for malignancy.
Frozen section diagnosis confirmed.

B. Left renal mass, partial nephrectomy:

Tumor Characteristics:

1. Histologic type: Papillary renal cell carcinoma, solid variant.
2. Tumor site: Left kidney.
3. Tumor focality: Unifocal.
4. Tumor size: 2.5 x 2.2 x 2.0 cm.
5. Macroscopic/microscopic extent of tumor: Tumor is confined to kidney.
6. Nuclear grade: Fuhrman grade 2/4.
7. Lymphovascular space invasion: No.
8. Sarcomatoid features: No.

Surgical Margin Status:

1. Resection margins are free of carcinoma.
However, one focus of tumor extends into, but not through the capsule and is within 0.5 mm of an inked margin.

Lymph Node Status:

Not applicable.

Other:

1. Other significant findings: Non-neoplastic renal tissue with no pathologic findings.
2. pTNM stage: T1a Nx Mx.

COMMENTS:

The neoplasm consists of mostly a solid pattern with focal papillary architecture at the periphery, and also contains a proliferation of foamy histiocytes within the tumor. Rare psammoma bodies are seen within the tumor. These features are most consistent with a solid variant of papillary renal cell carcinoma.

For

CLINICAL INFORMATION

CLINICAL HISTORY:

Preoperative Diagnosis: Renal and ureteral disease NOS

Postoperative Diagnosis:

Symptoms/Radiologic Findings:

SPECIMENS:

- A. Deep margin, left renal mass
- B. Deep renal mass

SPECIMEN DATA

GROSS DESCRIPTION:

A. The container is received labeled [REDACTED] deep margin left renal mass. The specimen consists of a piece of gray-tan to yellow-tan soft tissue, 0.6 x 0.5 x 0.3 cm. The specimen was examined at the time of surgery and the frozen section is subsequently entirely submitted in a single cassette label.

B. The container is received labeled [REDACTED], left renal mass. The specimen consists of a wedge section of kidney measuring 5.0 x 3.0 x 2.2 cm. The soft tissue margin is inked. On sectioning, there is a circumscribed gray-tan mass measuring 2.5 x 2.2 x 2.0 cm, that comes within 0.1 cm of the inked soft tissue margin. Received with the specimen are two cassettes, one green and one yellow, labeled [REDACTED], with the yellow additionally labeled -16 and the green additionally labeled -17. Representative sections are submitted in four cassettes.

[page 2 of 2]
INTRA-OPERATIVE CONSULTATION:

A FROZEN SECTION DIAGNOSIS: "Negative for malignancy." p. -

Source: NCI Genomic Data Commons file b979e3f7-3f83-405a-b12c-937a626af88d (TCGA-A4-8311.5E079150-D53B-4805-9C26-3B3F0FDB6992.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).